TCGA case TCGA-BB-7861 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Base of tongue; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1ae087ac-63f0-4cf9-b698-f5c13e1f4681

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C01; Tissue or organ of origin: Base of tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 56.3 years (20,563 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: TX; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T1; AJCC pathologic N: N1; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node dissection site: Neck, NOS.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 1; Lymph nodes tested: 12.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 43 days; Days to treatment end: 71 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 43 days; Days to treatment end: 71 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Cure; Days to treatment end: 71 days; Treatment outcome: No Measurable Disease; Chemo concurrent to radiation: Yes.

Follow-up (2 entries)
- Days to follow up: 310 days; Disease response: Tumor Free.
- Days to follow up: 682 days (1.9 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CDKN2A: Positive.
- Involved Tissue, NOS human papillomavirus (ISH): Positive.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BB-7861-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-BB-7861-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 15; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 40.
  Slide TCGA-BB-7861-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 27.
- Sample TCGA-BB-7861-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BB-7861-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Tobacco smoking history indicator: 2; Alcohol history documented: No.
- Follow-up form: Lost to follow-up: Yes; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Concurrent Chemotherapy; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 682 days; disease-specific survival: no event (censored), 682 days; disease-free interval: no event (censored), 682 days; progression-free interval: no event (censored), 682 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-BB-7861-01): tumor purity 0.36, ploidy 2.12, whole-genome doublings 0 (call status: maf_call).
